Gene-level copy-number profile of tumor specimen TCGA-EK-A2RA-01A from TCGA case TCGA-EK-A2RA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3; Age at diagnosis: 74.5 years (27,209 days).
Specimen TCGA-EK-A2RA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.62e462c2-6394-4a59-8814-236d0b0b6413.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2RA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b085392a-11d0-41a9-996e-bd99d497edbf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 10; copy number 2: 8,260; copy number 3: 29,981; copy number 4: 6,890; copy number 5: 6,502; copy number 6: 4,724; copy number 7: 2,984; copy number 8: 171; copy number 9: 297.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2RA-01A-11D-A18H-01): tumor purity 0.64, ploidy 3.5, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,452 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–93,909,456, 2,324 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr1:94,148,988–94,275,068, 1 gene, copy number 7 (within-gene range 5–7): ARHGAP29.
- chr1:94,247,819–100,739,045, 101 genes, copy number 7 (broad region; genes not listed).
- chr3:184,335,926–198,222,513, 316 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
